Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JR, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JR-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: M
ADM DATE:

PAT TYPE:

OPER DATE:

PROCEDURE: APMI

ADDITIONAL REPORT FOLLOWING ADDITIONAL SECTIONS:

=====

Please see diagnosis below.

PROCEDURE: APDX

1. Left adrenal, adrenalectomy: Adrenocortical carcinoma, low-grade, with capsular invasion. No vascular invasion identified.

I, _____ signing staff pathologist, have personally examined and interpreted the slides from this case.

OPER DATE:

PROCEDURE: SPHS

Left adrenalectomy.

PROCEDURE: SPGD

1. "Left adrenal mass" A 8 x 7 x 4 cm specimen of adrenal gland with large tan mass and adjacent adipose. Specimen received previously incised. Photographed and inked blue. Trimmed weight is 60 grams. Trimmed adrenal is 6.5 long and 2 cm wide x 0.1 cm thick with a 4.5 x 5 x 3.5 cm homogenous smooth round tan tumor protruding from it's midsection sections of the gland and tumor reveal the tumor to be tan and homogenous throughout. Appearing to arise in the cortex of he adrenal gland. The other cortex and medulla are unremarkable. A 2 cm area near the edge of the tumor is slightly more orange than the rest of the tumor.

- 1A. Representative section of adrenal gland adjacent to tumor.
- 1B. Representative section of adrenal gland with tumor.
- 1C. Representative section of tumor.
- 1D. Representative section of tumor.

ICD-6-3

Carcinoma, adrenal cortical 8370/3

Site Adrenal Gland, Cortex C74.2

QW 1/30/13

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 2

BIRTHDATE:

SEX: M

OPER DATE:

1E. Representative section of orange portion of tumor. '

PROCEDURE: SPDX

1. Left adrenal, adrenalectomy: Adrenocortical carcinoma, low-grade, with capsular invasion. Pending additional segments to identify vascular invasion.

I, _____ signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Site	hw 12/22/12	Yes	No
HPV A Discrepancy			
Pathology Discrepancy			
Direct/Synchronous Pathology Noted			
Case is (conf.):	RECEIVED / DISQUALIFIED		

Source: NCI Genomic Data Commons file 73dc5cf9-34b6-4a2f-8751-3c50d1788184 (TCGA-OR-A5JR.33E0DEF4-2538-4C8B-A71C-11B4F9D57E32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).